Gene-level copy-number profile of tumor specimen TCGA-FD-A62P-01A from TCGA case TCGA-FD-A62P, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 76.2 years (27,843 days).
Specimen TCGA-FD-A62P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.fc5abaf5-6f46-4c01-9d1f-2da68466c86c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FD-A62P-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0f83f4dc-5e6e-413f-8b1d-467505c9ee48

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 87; copy number 2: 714; copy number 3: 8,351; copy number 4: 17,999; copy number 5: 14,279; copy number 6: 8,617; copy number 7: 5,926; copy number 8: 1,268; copy number 9: 626; copy number 10: 852; copy number 11: 794; copy number 12: 28; copy number 13: 94; copy number 14: 36; copy number 16: 22; copy number 18: 16; copy number 19: 38; copy number 23: 6; copy number 24: 52.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FD-A62P-01A-32D-A30D-01): tumor purity 0.19, ploidy 5.3, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:60,383,141–60,387,445, 3 genes: AC007381.1, RNU1-32P, MIR4432.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,540 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:157,674,321–166,490,307, 277 genes, copy number 9–13 (within-gene range 3–13) (broad region; genes not listed).
- chr1:182,327,068–189,133,292, 116 genes, copy number 9 (broad region; genes not listed).
- chr3:83,384,445–83,437,728, 1 gene, copy number 11: AC023503.1.
- chr5:83,940,554–89,466,398, 61 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr6:20,212,087–21,602,383, 21 genes, copy number 9: AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3.
- chr6:62,460,940–62,548,272, 2 genes, copy number 10: DHFRP5, AL355375.1.
- chr8:66,964,099–74,896,302, 134 genes, copy number 9 (broad region; genes not listed).
- chr8:98,189,826–145,066,685, 744 genes, copy number 9–11 (broad region; genes not listed).
- chr11:29,335,878–29,989,328, 1 gene, copy number 16 (within-gene range 3–16): LINC02755.
- chr11:29,445,487–32,606,264, 47 genes, copy number 12–16: AC090124.1, AC110058.1, LINC02546, HNRNPRP2, AC107973.1, RN7SL240P, RPL7AP58, LINC01616, KCNA4, AL358944.1, AL358944.2, FSHB, ARL14EP, RPL12P30, MPPED2, AL353699.1, MPPED2-AS1, AL122014.1, DCDC1, CYCSP25, AL137804.1, DNAJC24, IMMP1L, ELP4, AC131571.1, PAX6, PAUPAR, AL035078.4, AL035078.1, AL035078.3, AL035078.2, U3, EIF4A2P5, RCN1, AL078612.1, THEM7P, AL078612.2, WT1, WT1-AS, AL049692.6, AL049692.1, AL049692.5, AL049692.3, AL049692.2, AL049692.4, EIF3M, HNRNPA3P9.
- chr12:66,767–34,249,958, 850 genes, copy number 10 (broad region; genes not listed).
- chr12:41,658,676–42,717,120, 28 genes, copy number 11: RNA5SP360, MTND2P17, MTND1P24, LINC02400, AC090630.1, AC006197.1, AC006197.2, AC023513.1, GXYLT1, YAF2, PPHLN1, AC020629.1, ZCRB1, MIR7851, SNORA74, AC079684.1, RNU6-249P, AC079601.2, Y_RNA, PRICKLE1, AC079601.1, AC079600.3, LINC02402, AC079600.2, AC079600.1, LINC02451, RPS27P21, LINC02450.
- chr12:59,322,765–61,232,937, 16 genes, copy number 11 (within-gene range 5–11): AC108721.2, AC108721.1, RNU6-279P, RNU6-871P, LINC02448, RNU4-20P, SLC16A7, AC079905.2, AC079905.1, AC080011.1, AC087883.2, AC087883.1, Y_RNA, AC090022.1, AC090022.2, AC090017.1.
- chr12:65,824,460–65,966,291, 1 gene, copy number 14 (within-gene range 8–14): HMGA2.
- chr12:65,851,340–71,927,248, 125 genes, copy number 14–24 (within-gene range 8–24) (broad region; genes not listed).
- chr16:46,469,341–50,742,815, 115 genes, copy number 11 (broad region; genes not listed).
- chr16:50,742,305–50,742,377, 1 gene, copy number 11: MIR3181.

Autosomal genes at a single copy (total copy number 1): 82. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
